Somatic mutation profile of tumor specimen 0DHOIU from CCDI case PBBUTS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.5 years (2,756 days).
Specimen 0DHOIU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d5f900ee-da09-496d-9071-d3a3af35c8eb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DHOGX (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cd9dabbf-57f8-49df-ac3d-6a1c9fafb110

The open-access MAF lists 3 somatic variants for this specimen: 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANO9 | c.771+47G>A | Intron (SNP) | VAF 68/213 reads (32%) | catalogued as rs369441724, COSV60449804; called by muse, varscan2
- POMT1 | c.1053-61T>G | Intron (SNP) | VAF 22/174 reads (13%) | called by muse, varscan2
- RIOK3 | c.179+93C>T | Intron (SNP) | VAF 50/214 reads (23%) | called by muse, varscan2
